Somatic mutation profile of tumor specimen MMRF_1668_1_BM_CD138pos (aliquot MMRF_1668_1_BM_CD138pos_T1_KBS5U_L04814) from MMRF case MMRF_1668, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.1 years (23,063 days).
Specimen MMRF_1668_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a22d8d92-ac72-4898-bf83-c65d14c5c6d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1668_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1668_1_PB_Whole_C3_KBS5U_L04826; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b7a845f-7f87-4ce5-8d9b-53b98bb20dea

The open-access MAF lists 158 somatic variants for this specimen: 54 protein-altering or splice-affecting, 14 silent, 90 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 50, Missense Mutation 45, Intron 24, Silent 14, 5'UTR 9, 5'Flank 3, Splice Region 3, Nonsense Mutation 2, RNA 2, 3'Flank 2, Splice Site 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 40/40 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2380C>T p.R794* | Nonsense Mutation (SNP) | VAF 25/40 reads (63%) | catalogued as COSV55946215; called by muse, mutect2, varscan2
- ADD3 | c.1585A>T p.I529F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53322984; called by muse, mutect2, varscan2
- AIM2 | c.1027A>C p.T343P | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs770198015, COSV63699722; called by mutect2, varscan2
- CCNK | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs758984649; called by muse, mutect2, varscan2
- CHRM2 | c.820T>A p.C274S | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as COSV57782167, COSV57785049; called by muse, mutect2, varscan2
- FNDC1 | c.1990G>C p.A664P | Missense Mutation (SNP) | VAF 63/67 reads (94%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV51941465; called by muse, mutect2, varscan2
- FNDC11 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs749910389; called by muse, mutect2, varscan2
- HMCN1 | c.15197C>A p.S5066Y | Missense Mutation (SNP) | VAF 12/440 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99629615; called by muse, mutect2
- IGHJ3 | c.13A>C p.I5L | Missense Mutation (SNP) | VAF 41/41 reads (100%) | PolyPhen benign (0.003); catalogued as rs190698203; called by muse, mutect2, varscan2
- IGHV2-70 | c.259A>G p.R87G | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs568002484; called by muse, varscan2
- IGHV2-70 | c.94A>G p.K32E | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751761340; called by muse, varscan2
- IGLV3-1 | c.151G>C p.A51P | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs376569759; called by muse, varscan2
- IGLV3-1 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs375782683; called by muse, mutect2, varscan2
- LRRC66 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100603074; called by muse, mutect2, varscan2
- MUC12 | c.1826C>T p.T609M (on ENST00000379442; = p.T466M on NM_001164462.1) | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs748803963; called by muse, mutect2, varscan2
- MYO5B | c.2839C>T p.Q947* | Nonsense Mutation (SNP) | VAF 15/124 reads (12%) | catalogued as rs766132905; called by muse, mutect2, varscan2
- PARN | c.659+4_659+7del | Splice Region (DEL) | VAF 38/90 reads (42%) | catalogued as rs759131762; called by pindel, varscan2
- PPP1R12C | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs754114232; called by muse, mutect2, varscan2
- SLC16A3 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs530738373; called by muse, mutect2, varscan2
- TRUB1 | c.595dup p.L199Pfs*20 | Frame Shift Ins (INS) | VAF 36/66 reads (55%) | catalogued as rs762997509; called by mutect2, varscan2
- ADAMTS12 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 116/231 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- ANKRD30A | c.3491A>T p.Y1164F (on ENST00000611781; = p.Y1108F on NM_052997.2) | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- ANKRD31 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 64/373 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C2orf50 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1H | c.1607C>A p.P536H | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- CCDC96 | c.730C>A p.R244S | Missense Mutation (SNP) | VAF 132/261 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- CSE1L | c.1822-2A>G p.X608_splice | Splice Site (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- CSRNP2 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 76/146 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTDSP2 | c.128G>C p.C43S | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- ELP5 | c.500T>A p.L167Q | Missense Mutation (SNP) | VAF 40/41 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAM107B | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- FAT1 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 195/443 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR107 | c.1660T>A p.Y554N (on ENST00000372406 / NM_001136557.2; = p.Y506N on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/207 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IGKJ5 | chr2:88860600 del GTGATCCACAGTGTTAACTTAATTAC | Missense Mutation (DEL) | VAF 81/261 reads (31%) | called by pindel, varscan2
- KBTBD3 | c.361A>C p.N121H | Missense Mutation (SNP) | VAF 101/223 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC2 | c.1661T>A p.L554H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MXRA5 | c.4700C>T p.A1567V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MYO3A | c.4844A>G p.Q1615R | Missense Mutation (SNP) | VAF 67/123 reads (54%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NOD1 | c.87_89dup p.L30dup | In Frame Ins (INS) | VAF 56/122 reads (46%) | called by mutect2, varscan2
- PHF19 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLA2G6 | c.795G>A p.K265= | Splice Region (SNP) | VAF 56/107 reads (52%) | called by muse, mutect2, varscan2
- POLR3A | c.3040T>C p.F1014L | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- RPL23A | c.209+7A>T | Splice Region (SNP) | VAF 60/147 reads (41%) | called by muse, mutect2, varscan2
- SCN10A | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- SIPA1 | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SLC5A12 | c.1307A>C p.K436T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.14); called by muse, mutect2
- SUN1 | c.446T>A p.F149Y (on ENST00000405266 / NM_001367651.1; = p.F99Y on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); called by muse, mutect2
- TAS2R46 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 146/301 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); called by muse, varscan2
- TBX19 | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TCF20 | c.5800-1G>C p.X1934_splice | Splice Site (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- TMF1 | c.247A>G p.K83E | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- ZACN | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CCDC142 | c.1183T>C p.L395= | Silent (SNP) | VAF 49/141 reads (35%) | catalogued as rs1209970024; called by muse, mutect2, varscan2
- CHRM2 | c.819C>T p.N273= | Silent (SNP) | VAF 59/118 reads (50%) | called by muse, mutect2, varscan2
- CUBN | c.5517C>T p.S1839= | Silent (SNP) | VAF 59/133 reads (44%) | catalogued as rs754868648, COSV64727422; called by muse, mutect2, varscan2
- E2F2 | c.399G>A p.S133= | Silent (SNP) | VAF 62/90 reads (69%) | catalogued as rs575411299; called by muse, varscan2
- GRIN2B | c.3444C>T p.H1148= | Silent (SNP) | VAF 7/174 reads (4%) | catalogued as rs1467092221, COSV101663180; called by muse, mutect2
- HSP90B1 | c.1569C>T p.S523= | Silent (SNP) | VAF 95/247 reads (38%) | catalogued as rs1161213176; called by muse, mutect2, varscan2
- IFNGR2 | c.1008G>A p.T336= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as rs121913221; ClinVar: likely benign / not provided; called by muse, mutect2, varscan2
- IGKV5-2 | c.243A>G p.R81= | Silent (SNP) | VAF 79/80 reads (99%) | called by muse, mutect2, varscan2
- KIF3C | c.291C>T p.G97= | Silent (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- LRFN5 | c.672C>A p.T224= | Silent (SNP) | VAF 122/128 reads (95%) | called by muse, varscan2
- PPP2R3A | c.2694A>G p.E898= | Silent (SNP) | VAF 78/151 reads (52%) | called by muse, mutect2, varscan2
- RELCH | c.1375A>C p.R459= | Silent (SNP) | VAF 40/331 reads (12%) | called by muse, mutect2, varscan2
- SLC25A32 | c.333A>T p.T111= | Silent (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- SMARCD3 | c.571C>T p.L191= (on ENST00000262188 / NM_001003801.2; = p.L178= on NM_003078.4) | Silent (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- AC005865.1 | n.1665T>A | RNA (SNP) | VAF 36/74 reads (49%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-274G>A | 5'UTR (SNP) | VAF 230/386 reads (60%) | catalogued as rs990990410, COSV59350872; called by muse, mutect2, varscan2
- AC116366.2 | c.-637-10155A>G | Intron (SNP) | VAF 109/237 reads (46%) | called by muse, mutect2, varscan2
- ACBD6 | c.*1460A>G | 3'UTR (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2
- ADARB2 | c.*21G>A | 3'UTR (SNP) | VAF 22/46 reads (48%) | catalogued as rs1302955306; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852698 G>A | 3'Flank (SNP) | VAF 20/64 reads (31%) | catalogued as rs761484417; called by muse, mutect2, varscan2
- ARL14EP | c.-63-2046T>C | Intron (SNP) | VAF 60/125 reads (48%) | called by muse, mutect2, varscan2
- BAG4 | c.*22A>T | 3'UTR (SNP) | VAF 71/411 reads (17%) | called by muse, mutect2, varscan2
- BDH1 | c.84-95C>T | Intron (SNP) | VAF 58/94 reads (62%) | catalogued as rs968311831; called by muse, mutect2, varscan2
- BLCAP | c.-148T>C | 5'UTR (SNP) | VAF 41/79 reads (52%) | catalogued as rs534859327; called by muse, mutect2, varscan2
- CAMK1D | c.*861A>C | 3'UTR (SNP) | VAF 11/70 reads (16%) | called by mutect2, varscan2
- CBLB | c.*3092C>A | 3'UTR (SNP) | VAF 22/165 reads (13%) | called by muse, mutect2, varscan2
- CHORDC1 | c.492+1150A>T | Intron (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- CSPP1 | c.*126del | 3'UTR (DEL) | VAF 79/184 reads (43%) | called by mutect2, pindel, varscan2
- CYP2U1 | c.*451_*453del | 3'UTR (DEL) | VAF 17/80 reads (21%) | called by pindel, varscan2
- DPP8 | c.*4099A>C | 3'UTR (SNP) | VAF 53/109 reads (49%) | called by muse, mutect2, varscan2
- DUOX1 | c.1216+124G>T | Intron (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2
- DYRK2 | c.-135G>C | 5'UTR (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- EDIL3 | c.*1518A>T | 3'UTR (SNP) | VAF 102/211 reads (48%) | called by muse, mutect2, varscan2
- EPHA5 | c.3008+1356T>A | Intron (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- ERCC3 | c.522-171C>T | Intron (SNP) | VAF 11/16 reads (69%) | catalogued as rs1451188175; called by muse, mutect2, varscan2
- FAM135A | c.3966-102T>C | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- FAT4 | c.*86T>G | 3'UTR (SNP) | VAF 217/418 reads (52%) | called by muse, mutect2, varscan2
- FGD6 | c.*1573A>T | 3'UTR (SNP) | VAF 4/11 reads (36%) | catalogued as rs1365360816; called by muse, varscan2
- FZD4 | c.*4312G>A | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- GDA | c.*733T>A | 3'UTR (SNP) | VAF 22/148 reads (15%) | called by muse, mutect2, varscan2
- GIPC2 | c.*2373A>T | 3'UTR (SNP) | VAF 37/66 reads (56%) | called by muse, mutect2, varscan2
- HHIPL1 | c.*1173G>A | 3'UTR (SNP) | VAF 56/72 reads (78%) | catalogued as rs893410083; called by muse, mutect2, varscan2
- HMGCLL1 | c.632+1853dup | Intron (INS) | VAF 109/242 reads (45%) | catalogued as rs1017998578; called by mutect2, varscan2
- HMGCLL1 | c.632+805G>A | Intron (SNP) | VAF 42/118 reads (36%) | called by muse, mutect2, varscan2
- HOOK3 | c.*503G>C | 3'UTR (SNP) | VAF 11/148 reads (7%) | called by muse, mutect2
- INHBA | c.*859A>T | 3'UTR (SNP) | VAF 14/187 reads (7%) | called by muse, mutect2
- IYD | c.*3860G>A | 3'UTR (SNP) | VAF 3/47 reads (6%) | catalogued as rs1006692372; called by muse, mutect2
- KDR | c.*470G>A | 3'UTR (SNP) | VAF 111/239 reads (46%) | catalogued as rs994073099; called by muse, mutect2, varscan2
- KLC3 | c.-8-96G>T | Intron (SNP) | VAF 42/86 reads (49%) | called by mutect2, varscan2
- KLHDC3 | c.-15C>G | 5'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- L3MBTL4 | c.1471+15315G>A | Intron (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- LL22NC03-63E9.3 | n.1326C>T | RNA (SNP) | VAF 58/144 reads (40%) | catalogued as rs372076385; called by muse, mutect2, varscan2
- LMNA | c.*942T>G | 3'UTR (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- LONRF2 | c.*5586C>T | 3'UTR (SNP) | VAF 58/120 reads (48%) | called by muse, mutect2, varscan2
- LPP | c.1241-13524C>T | Intron (SNP) | VAF 328/631 reads (52%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.1627+38C>T | Intron (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- MBL2 | c.*158A>C | 3'UTR (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- MED6 | c.274+86G>A | Intron (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- MEF2C | c.*1886A>G | 3'UTR (SNP) | VAF 39/185 reads (21%) | called by muse, mutect2, varscan2
- MIR29B2 | chr1:207802573 C>G | 5'Flank (SNP) | VAF 33/164 reads (20%) | called by muse, mutect2, varscan2
- MRPS18C | c.151-155G>A | Intron (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- NOS1 | c.*5390G>A | 3'UTR (SNP) | VAF 3/46 reads (7%) | catalogued as rs1487210366; called by muse, mutect2
- NOX5 | c.*4173C>T | 3'UTR (SNP) | VAF 71/129 reads (55%) | called by muse, mutect2, varscan2
- NTNG1 | c.1087+1924A>T | Intron (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- PCDH18 | c.*442del | 3'UTR (DEL) | VAF 87/205 reads (42%) | catalogued as rs1278545215; called by mutect2, pindel, varscan2
- PLCL2 | c.327+47758A>C | Intron (SNP) | VAF 64/95 reads (67%) | called by muse, mutect2, varscan2
- PLD1 | c.*1177T>C | 3'UTR (SNP) | VAF 46/107 reads (43%) | called by muse, mutect2, varscan2
- PPHLN1 | chr12:42448380 del TCTTAAAG | 3'Flank (DEL) | VAF 31/68 reads (46%) | called by pindel, varscan2
- PTGDR2 | c.*469C>T | 3'UTR (SNP) | VAF 39/215 reads (18%) | called by muse, mutect2, varscan2
- RAB33B | c.*2698T>A | 3'UTR (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- RABL3 | c.*2595G>A | 3'UTR (SNP) | VAF 50/109 reads (46%) | called by muse, mutect2, varscan2
- RAD54L2 | c.1340-68A>G | Intron (SNP) | VAF 10/96 reads (10%) | catalogued as rs1414261374; called by muse, mutect2, varscan2
- ROBO1 | c.*350C>T | 3'UTR (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- ROR1 | c.*2196del | 3'UTR (DEL) | VAF 19/61 reads (31%) | catalogued as rs564823371; called by mutect2, pindel, varscan2
- RPH3A | c.*1683C>G | 3'UTR (SNP) | VAF 10/306 reads (3%) | called by muse, mutect2
- RUNX1T1 | chr8:92103034 C>A | 5'Flank (SNP) | VAF 2/10 reads (20%) | called by muse, mutect2
- S1PR2 | c.-43+720T>C | Intron (SNP) | VAF 44/94 reads (47%) | called by muse, varscan2
- SH3PXD2B | c.*613T>G | 3'UTR (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2
- SOX4 | c.*2312A>C | 3'UTR (SNP) | VAF 65/161 reads (40%) | called by muse, mutect2, varscan2
- SP3 | c.*217C>G | 3'UTR (SNP) | VAF 95/140 reads (68%) | catalogued as COSV59471186; called by muse, mutect2, varscan2
- SPACA6 | c.-160C>A | 5'UTR (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- STMN1 | c.-6T>G | 5'UTR (SNP) | VAF 103/571 reads (18%) | called by muse, mutect2, varscan2
- TACSTD2 | c.*672G>A | 3'UTR (SNP) | VAF 25/82 reads (30%) | catalogued as rs1399030202; called by muse, mutect2
- TAGAP | c.*376T>A | 3'UTR (SNP) | VAF 39/40 reads (98%) | called by muse, mutect2, varscan2
- TLL2 | c.-190T>A | 5'UTR (SNP) | VAF 17/51 reads (33%) | catalogued as rs962502073; called by muse, mutect2, varscan2
- TMEM131 | c.-51C>T | 5'UTR (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- TMEM64 | c.*3230dup | 3'UTR (INS) | VAF 38/119 reads (32%) | called by mutect2, pindel, varscan2
- TMPRSS5 | c.-66C>T | 5'UTR (SNP) | VAF 117/236 reads (50%) | called by muse, mutect2, varscan2
- TOP3A | c.500-19A>G | Intron (SNP) | VAF 15/281 reads (5%) | called by muse, mutect2
- TP53INP1 | c.*555G>T | 3'UTR (SNP) | VAF 97/189 reads (51%) | called by muse, mutect2, varscan2
- TRAF3 | c.*113G>A | 3'UTR (SNP) | VAF 8/9 reads (89%) | called by muse, varscan2
- TTC7B | c.*192del | 3'UTR (DEL) | VAF 26/28 reads (93%) | catalogued as rs199994385; called by mutect2, varscan2
- TXLNGY | chrY:19590318 T>C | 5'Flank (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- URGCP | c.15-97G>A | Intron (SNP) | VAF 11/27 reads (41%) | catalogued as rs756600623; called by muse, mutect2, varscan2
- USP38 | c.2967+248C>T | Intron (SNP) | VAF 60/106 reads (57%) | catalogued as rs576519611; called by muse, mutect2, varscan2
- USP38 | c.2967+369T>G | Intron (SNP) | VAF 72/147 reads (49%) | called by muse, mutect2, varscan2
- USP38 | c.*53T>G | 3'UTR (SNP) | VAF 102/215 reads (47%) | called by muse, mutect2, varscan2
- USP38 | c.*711T>G | 3'UTR (SNP) | VAF 67/163 reads (41%) | called by muse, mutect2, varscan2
- WASL | c.*110A>G | 3'UTR (SNP) | VAF 32/68 reads (47%) | called by muse, varscan2
- ZCCHC14 | c.*979A>G | 3'UTR (SNP) | VAF 35/114 reads (31%) | called by muse, mutect2, varscan2
- ZIC3 | c.*664T>G | 3'UTR (SNP) | VAF 45/138 reads (33%) | called by muse, mutect2, varscan2
- ZNF385D | c.*1084del | 3'UTR (DEL) | VAF 79/158 reads (50%) | called by mutect2, pindel, varscan2
- ZNF572 | c.*1063A>T | 3'UTR (SNP) | VAF 52/100 reads (52%) | called by muse, mutect2, varscan2
- ZNF704 | c.*4744G>T | 3'UTR (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
